Surgical pathology report (de-identified scan), TCGA case TCGA-UC-A7PI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Washington, specimen TCGA-UC-A7PI-01A (Primary Tumor).

[page 1 of 5]
Patient ID:

COLLECTED:

RECEIVED:

***** THIS IS A REVISED OR CORRECTED REPORT *****

**** PLEASE SEE END OF REPORT FOR DETAIL OF CORRECTIONS ****

***** THIS IS AN ADDENDUM REPORT *****

Reason for Revision #1 (Addendum): Diagnosis Revised

CLINICAL DATA:

Cervical carcinoma.

GROSS DESCRIPTION:

A) Received in formalin designated "right pelvic lymph nodes" are multiple fragments of yellow lobulated adipose tissue admixed with lymph node candidates measuring 4 x 4 x 1 cm in aggregate. Specimen bluntly dissected and entirely submitted as follows: A1- two lymph node candidates; A2- one lymph node candidate; A3- one lymph node candidate; A4- four lymph node candidates; A5- two lymph node candidates; A6- two lymph node candidates; A7- two lymph node candidates; A8- two lymph node candidates.

B) Received in formalin designated "right common iliac and para-aortic lymph nodes" is a 6 x 1.5 x 0.5 cm fragment of yellow lobulated adipose tissue admixed with lymph nodes. Specimen entirely submitted as follows: B1 - one bisected lymph node; B2 - two bisected lymph nodes; B3 - one bisected lymph node; B4-B5 - two bisected lymph nodes.

C) Received in formalin designated "left pelvic lymph nodes" are multiple fragments of yellow lobulated adipose tissue admixed with several lymph nodes measuring 4.5 x 4 x 1.5 cm in aggregate. Specimen entirely submitted as follows: C1 - two lymph node candidates; C2 - two lymph node candidates; C3 - two lymph node candidates; C4 - two lymph node candidates; C5 - two lymph node candidates; C6 - two lymph node candidates; C7-C8 - one bisected lymph node candidate; C9 - one lymph node candidate; C10 - two lymph node candidates; C11 - three lymph node candidates; C12-C13 - two lymph node candidates, bisected.

D) Received in formalin designated "left common iliac and para-aortic lymph nodes" is a 2.5 x 1 x 0.5 cm portion of yellow lobulated adipose tissue admixed with two lymph node candidates. Specimen bisected and entirely submitted in two cassettes.

E) Received fresh designated "uterus and cervix, bilateral tube ovaries" is a 141 gm radical hysterectomy bilateral salpingo-oophorectomy specimen which includes uterus (141 gm, 5.5 cm CC x 7.3 cm SI x 3.5 cm AP) and attached cervix and vaginal cuff, right ovary (3 x 1.5 x 1.5 cm), right fallopian tube (7.5 cm long x 0.5 cm in diameter), left ovary (2.5 cm x 2.5 cm x 1.8 cm), and left

CCF ICD-O-3
Adenocarcinoma, endometroid NOS
path 8380/3
Adenocarcinoma papillary NOS
CCF 8260/3
Date: Endoscopy
path C53.0
CCF C53.9
9/27/13

[page 2 of 5]
fallopian tube (6 cm long x 0.5 cm in diameter). The surgical margin is inked black. The serosa is glistening with no masses identified. The entire exocervix is distorted by an irregular, well demarcated friable white mass that measures 2.6 x 2.4 cm AP located mostly on the anterior surface, 1.6 cm from the anterior vaginal margin and 1.5 cm from the posterior vaginal cuff margin.. The cervical os is distorted by the mass, measuring approximately 0.3 cm in diameter and appears patent. The anterior vaginal cuff margin is inked green and the posterior vaginal cuff margin blue and the uterus is bisected to reveal a 3 cm long cervical canal with a tan herringbone mucosa. The distal cervical canal (1.2 cm long posterior and 0.7 cm long anterior) appears involved by the tumor, however, the proximal aspect of the cervical canal as well as the lower uterine segment appear grossly unremarkable. The cervical canal is serially sectioned into approximately 0.4 cm thick slices to reveal a 2.6 x 2.4 x 1.4 cm white-tan firm tumor. The endometrial cavity has a pink endometrium measuring 0.1 cm thick with no masses or lesions identified. The myometrium is white rubbery measuring 1.5 cm thick and contains one submucosal leiomyoma (0.5 cm in greatest dimension) that has a tan white whorled appearance without hemorrhage or necrosis. The parametrium is serially sectioned and no lymph nodes are

identified. The left ovary appears yellow, cerebriform with a 2 x 1.3 x 0.7 cm pale tan nodule. No papillary excrescences are identified. The ovary is bisected to reveal multiple physiologic cysts. The previously described nodule appears to be a cyst with hemorrhagic contents. The cyst lining is smooth with no papillary excrescences identified. The left fallopian tube is serially sectioned to reveal a stellate patent lumen with no masses identified. The right ovary appears yellow lobulated with smooth and glistening external aspect with no papillary excrescences identified. The ovary is bisected to reveal a few physiologic cysts with no masses identified. The right tube is serially sectioned to reveal a stellate patent lumen with no masses identified. Representative sections are submitted as follows: E1 - anterior vaginal cuff; E2 - left parametrium; E3 - right parametrium; E4-E6 - composite anterior cervical canal and lower uterine segment (E4 cervix, E5 mid section, E6 lower uterine segment); E7-E9 - composite section posterior cervical canal and lower uterine segment (E7 cervix, E8 mid section, E9 lower uterine segment); E10-E11 - section of tumor anterior; E12 - section of tumor posterior; E13-E14 - composite endomyometrium anterior; E15 - endomyometrium posterior; E16 - left ovary; E17 - left fallopian tube; E18 - right ovary and fallopian tube; E19 - right fallopian tube, fimbriated end.

[page 3 of 5]
FINAL DIAGNOSIS:

A) Right pelvic lymph nodes, dissection: Nineteen lymph nodes with no evidence of carcinoma (0/19).

B) Right common iliac and para-aortic lymph nodes, dissection: Six lymph nodes with no evidence of carcinoma (0/6).

C) Left pelvic lymph nodes, dissection: Sixteen lymph nodes with no evidence of carcinoma (0/16).

D) Left common iliac and para-aortic lymph nodes, dissection: Two lymph nodes with no evidence of carcinoma (0/2).

E) Uterus, cervix and bilateral ovaries and fallopian tubes, radical hysterectomy and bilateral salpingo-oophorectomy:

1. Papillary (villoglandular) adenocarcinoma of the cervix. See Summary Cancer Data below.

2. Foci of adenomyosis.

3. Bilateral tubes and ovaries with no diagnostic alteration.

4. 4 parametrial lymph nodes with no evidence of carcinoma.

5. See comment.

SUMMARY CANCER DATA:

Specimens Included in This Summary

Specimens: A: Lymph node, pelvic right

B: Common iliac lymph node

C: Lymph node, pelvic left

D: Common iliac lymph node

E: Uterus with ovaries and tubes

Surgical Procedure and Location

Specimen Type: Radical or modified radical hysterectomy (includes parametria and vaginal cuff)

Other Organs Present: Right ovary

Left ovary

Right fallopian tube

Left fallopian tube

Uterine corpus

Vagina

Chemotherapy and/or Radiation Therapy Prior to Surgery: Unknown/History not provided

Characteristics of Neoplasm

Tumor Site (check all that apply): Anterior cervix

Posterior cervix

Histologic Type: Papillary adenocarcinoma, NOS (82603)

Comment about histologic type: Circumferential neoplasia.

[page 4 of 5]
Histologic Grade: G1: Well differentiated

Minimum Pathologic Stage

Local Extent

Tumor Extent and Stage Includes Data from Case(s): Current case

Tumor Size: Greatest diameter 2.6cm x 2nd diameter: 2.4cm x 3rd diameter: 1.4cm

Cervical Invasion: Depth of Invasion: 1cm / Thickness of Cervix: 2.2cm

Primary Tumor (pT): pT1b1: Macroscopically visible lesion <= 4.0 cm in greatest dimension

Comment about Local Extension: Lower uterine segment and endomyometrium free of carcinoma.

Lymph Node Status

Node Summary: Nodes with carcinoma: 0 / Total nodes examined: 47

Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis

Distant Metastases

Distant Metastasis (pM): pMX: Cannot be assessed

Final Surgical Resection Margins

Invasive carcinoma: All margins negative for invasive carcinoma

Distance of invasive carcinoma from closest margin: 2cm

Closest invasive carcinoma margin: Anterior and posterior vaginal cuff.

In Situ Carcinoma Margin: Carcinoma in situ absent at distal cervical/vaginal margin

Other Findings and Possible Prognostic Indicators

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

COMMENT:

... reviewed slides E4 and E7 and concurs with the diagnosis.

Procedures used to establish the diagnosis:

Routine

Resident

Pathologist

Electronically signed

In compliance with regulations, the pathologist's signature on this report indicates that the case has been personally reviewed, and the diagnosis made or confirmed by, the Attending Pathologist. Microscopic examination was used to arrive at the diagnosis unless indicated otherwise.

[page 5 of 5]
ADDENDUM REASON:

This addendum is issued to correct the histologic classification of the carcinoma in part E.

The carcinoma is well differentiated, but is clearly invasive, is not exophytic and does not meet criteria for well differentiated papillary villoglandular carcinoma. I would interpret it as well differentiated endometrioid carcinoma. In addition, the closest inked margin is approximately 1.4 cm. The remainder of the diagnosis is unchanged.

This opinion was discussed with

Pathologist

Electronically signed

In compliance with regulations, the pathologist's signature on this report indicates that the case has been personally reviewed, and the diagnosis made or confirmed by, the Attending Pathologist. Microscopic examination was used to arrive at the diagnosis unless indicated otherwise.

~ end of report ~

Specimen from endocervix,
p/w TSS Surgeon. BCR

Source: NCI Genomic Data Commons file bc808d34-f1fc-45e6-bb5f-df475c7621ee (TCGA-UC-A7PI.9FA775F9-4A52-498E-93B3-BAEE344324CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).